Somatic mutation profile of tumor specimen MP2PRT-PARHDT-TMP1-B (aliquot MP2PRT-PARHDT-TMP1-B-1-0-D-A834-36) from MP2PRT case MP2PRT-PARHDT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,504 days).
Specimen MP2PRT-PARHDT-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4d18eb9-1aba-4b22-b6f3-e533f2ed1d9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARHDT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARHDT-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d95c3c38-cb9c-4d3b-9a56-205a87d664cf

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Del 1, Silent 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 135/525 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHERP | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 140/687 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.65); catalogued as rs1282831765; called by muse, mutect2, varscan2
- DLGAP1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs951699696, COSV59802690; called by muse, mutect2
- DNAH3 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1013012929, COSV54511759, COSV99770890; called by muse, mutect2
- GATA6 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 210/526 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs759639860, COSV52525417; called by muse, mutect2, varscan2
- GRM4 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 106/605 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65216335; called by muse, mutect2, varscan2
- MAP1A | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 82/632 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752455669; called by muse, mutect2, varscan2
- OBP2A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 132/277 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1206641570, COSV59792794; called by muse, mutect2, varscan2
- RUNX1 | c.332A>G p.E111G (on ENST00000344691 / NM_001001890.3; = p.E138G on NM_001754.5) | Missense Mutation (SNP) | VAF 64/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55877916; called by muse, mutect2, varscan2
- DCAF4L2 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 85/539 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- HECW2 | c.1364_1369delinsG p.T455Sfs*8 | Frame Shift Del (DEL) | VAF 90/374 reads (24%) | called by pindel, varscan2*
- IGKV2D-26 | chr2:89986702 TCCCACAGTGCTACAGCCCTGAGCACAAACCTCTCTGCTTGA>CCCTCTCGCCCTGAACAAAAACCTCCCGCTGG | Missense Mutation (DEL) | VAF 6/56 reads (11%) | called by mutect2*, pindel
- OR5L1 | c.219C>A p.Y73* | Nonsense Mutation (SNP) | VAF 20/562 reads (4%) | called by muse, mutect2
- PRAMEF19 | c.795G>C p.R265S | Missense Mutation (SNP) | VAF 39/398 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2
- ZNF679 | c.1092C>T p.S364= | Silent (SNP) | VAF 24/506 reads (5%) | called by muse, mutect2
- REXO1L1P | n.1515C>T | RNA (SNP) | VAF 98/1524 reads (6%) | catalogued as rs763779559; called by muse, mutect2
